Somatic mutation profile of tumor specimen C3L-01048-02 (aliquot CPT0217190006) from CPTAC case C3L-01048, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.5 years (22,109 days).
Specimen C3L-01048-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Temporal Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe6ae1a5-c0e1-4f45-9e6e-2cf18a102eef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01048-31 (Blood Derived Normal), aliquot CPT0220100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf7fd9a2-5efa-4944-9810-8fddba9dd48e

The open-access MAF lists 118 somatic variants for this specimen: 68 protein-altering or splice-affecting, 33 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 33, Intron 9, RNA 7, Nonsense Mutation 5, Frame Shift Del 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 291/311 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131691013, CM120849, CM134998, COSV52681833, COSV52696302, COSV52721346, COSV53165479; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACE | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 229/502 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373970727; called by muse, mutect2, varscan2
- ADAM7 | c.2050G>A p.G684R | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs200101638, COSV51548017; called by muse, mutect2, varscan2
- ADGB | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58864505; called by muse, mutect2, varscan2
- ASZ1 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 147/238 reads (62%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs200922374, COSV52916699; called by muse, mutect2, varscan2
- BRCA1 | c.2788C>T p.P930S | Missense Mutation (SNP) | VAF 102/236 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV58796304; called by muse, mutect2, varscan2
- C2CD6 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs576434498, COSV53793572; called by muse, mutect2, varscan2
- CAPN13 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 107/498 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.098); catalogued as rs773969358, COSV54429933, COSV54435521; called by muse, mutect2, varscan2
- CYP2S1 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 268/985 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs752402676, COSV59505726; called by muse, mutect2, varscan2
- DNAH5 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 139/340 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs150601733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJA4 | c.469C>T p.R157W (on ENST00000343789; = p.R186W on NM_018602.3) | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs752111684; called by muse, mutect2, varscan2
- ELK3 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.953); catalogued as rs1183513560; called by muse, mutect2, varscan2
- IL1RL1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as rs761694081; called by muse, mutect2, varscan2
- KEL | c.974C>G p.T325R | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs761304758; called by muse, mutect2, varscan2
- KIF12 | c.1724G>A p.R575Q (on ENST00000640217; = p.R437Q on NM_138424.1) | Missense Mutation (SNP) | VAF 109/263 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as rs764888900, COSV65117372; called by muse, mutect2, varscan2
- KIF7 | c.3430C>T p.R1144W | Missense Mutation (SNP) | VAF 101/204 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571807299; called by muse, mutect2, varscan2
- KIT | c.2150G>T p.S717I | Missense Mutation (SNP) | VAF 153/437 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as rs1239669396; called by muse, mutect2, varscan2
- MCF2L | c.1397C>T p.T466M (on ENST00000375608; = p.T434M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs751741111, COSV65047726; called by muse, mutect2, varscan2
- MYBPC3 | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM121858; called by muse, mutect2, varscan2
- NAA10 | c.387-6C>T | Splice Region (SNP) | VAF 271/294 reads (92%) | catalogued as COSV63132891; called by muse, mutect2, varscan2
- NCKAP1L | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779642333, COSV53206082; called by muse, mutect2, varscan2
- NPY4R | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs371172497; called by muse, mutect2, varscan2
- OR2W1 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs774114077, COSV65851453; called by muse, mutect2
- PABPC5 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 131/140 reads (94%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV100442529; called by muse, mutect2, varscan2
- PRRC2B | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 186/451 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.727); catalogued as rs766029882, COSV61935187; called by muse, mutect2, varscan2
- RANBP2 | c.6722G>A p.S2241N | Missense Mutation (SNP) | VAF 222/560 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1481038887; called by muse, mutect2, varscan2
- SATB1 | c.398A>G p.Q133R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs774149487; called by muse, mutect2, varscan2
- SI | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200745562, COSV52269530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC9A1 | c.1933C>T p.R645W | Missense Mutation (SNP) | VAF 117/249 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs752306761, COSV56055353; called by muse, mutect2, varscan2
- SMARCE1 | c.86A>G p.N29S | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as rs760888905; called by muse, mutect2, varscan2
- SRRM4 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 108/230 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as COSV57419797; called by muse, mutect2, varscan2
- TMEM233 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755987884, COSV101460112; called by muse, mutect2, varscan2
- TTN | c.50428C>T p.R16810* (on ENST00000591111; = p.R9386* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 25/52 reads (48%) | catalogued as rs1440093502, COSV60105753; called by muse, mutect2, varscan2
- TTN | c.4291C>T p.R1431W (on ENST00000591111; = p.R1385W on NM_003319.4) | Missense Mutation (SNP) | VAF 108/223 reads (48%) | PolyPhen possibly damaging (0.534); catalogued as rs139636676; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- UBR3 | c.4423G>A p.A1475T | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.368); catalogued as COSV55855267; called by muse, mutect2, varscan2
- ZBTB46 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 53/427 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55507427; called by muse, mutect2, varscan2
- ZP1 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as rs763577041; called by muse, mutect2, varscan2
- AHNAK | c.14030C>T p.P4677L | Missense Mutation (SNP) | VAF 258/592 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCORL1 | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- C20orf96 | c.646G>A p.D216N (on ENST00000360321 / NM_153269.3; = p.D215N on NM_080571.1) | Missense Mutation (SNP) | VAF 102/449 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CHKA | c.1123del p.Q375Sfs*27 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- CPB1 | c.1211C>G p.A404G | Missense Mutation (SNP) | VAF 115/228 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DMBX1 | c.418A>T p.K140* | Nonsense Mutation (SNP) | VAF 70/170 reads (41%) | called by muse, mutect2
- ENO4 | c.342G>C p.E114D (on ENST00000622726; = p.E113D on NM_001242699.2) | Missense Mutation (SNP) | VAF 183/200 reads (92%) | SIFT tolerated (0.07); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FAM71F1 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIMAP2 | c.131G>C p.R44T | Missense Mutation (SNP) | VAF 132/251 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- GLI1 | c.1922A>T p.D641V | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ITGB2 | c.719T>A p.M240K | Missense Mutation (SNP) | VAF 128/249 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- KCNJ12 | c.71C>A p.T24N | Missense Mutation (SNP) | VAF 189/507 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KCNU1 | c.1610T>A p.M537K | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRD1 | c.516C>A p.D172E | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MROH5 | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 146/383 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- MSR1 | c.1124G>C p.C375S | Missense Mutation (SNP) | VAF 143/345 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NMUR2 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 82/478 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4A16 | c.310T>A p.L104I | Missense Mutation (SNP) | VAF 103/231 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PCDH11X | c.700A>C p.I234L | Missense Mutation (SNP) | VAF 221/236 reads (94%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHM1 | c.958T>A p.S320T | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PRKX | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 46/47 reads (98%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RIF1 | c.6201_6204del p.C2068Tfs*5 | Frame Shift Del (DEL) | VAF 50/161 reads (31%) | called by pindel, varscan2
- RYR3 | c.6742A>G p.I2248V | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SETMAR | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- SLC22A1 | c.1157A>G p.E386G | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMCHD1 | c.1385A>T p.E462V | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- SYNE1 | c.2355G>A p.M785I (on ENST00000367255 / NM_182961.4; = p.M792I on NM_033071.3) | Missense Mutation (SNP) | VAF 104/302 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAFA2 | c.308A>T p.E103V | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TGIF2LY | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 313/382 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- WNT5B | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 170/347 reads (49%) | called by muse, mutect2, varscan2
- ZFP30 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.1254C>T p.H418= | Silent (SNP) | VAF 221/544 reads (41%) | catalogued as rs758041605, COSV99202823; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAMTS8 | c.1812C>T p.D604= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as rs767112990; called by muse, mutect2, varscan2
- CRISPLD1 | c.147C>G p.A49= | Silent (SNP) | VAF 158/420 reads (38%) | called by muse, varscan2
- CSAD | c.627A>G p.R209= (on ENST00000444623 / NM_001244705.2; = p.R236= on NM_015989.5) | Silent (SNP) | VAF 145/330 reads (44%) | called by muse, mutect2, varscan2
- DCST2 | c.1071C>A p.I357= | Silent (SNP) | VAF 153/380 reads (40%) | called by muse, mutect2, varscan2
- ELOVL3 | c.663C>T p.Y221= | Silent (SNP) | VAF 109/135 reads (81%) | called by muse, mutect2, varscan2
- EMB | c.93G>A p.S31= | Silent (SNP) | VAF 34/184 reads (18%) | called by muse, mutect2, varscan2
- EPHA6 | c.1968C>T p.L656= (on ENST00000389672 / NM_001080448.3; = p.L48= on NM_173655.4) | Silent (SNP) | VAF 69/175 reads (39%) | catalogued as rs374284939, COSV101066161; called by muse, mutect2, varscan2
- FGD2 | c.618G>A p.A206= | Silent (SNP) | VAF 90/294 reads (31%) | catalogued as rs752073145; called by muse, mutect2, varscan2
- GALNTL6 | c.126C>T p.P42= | Silent (SNP) | VAF 104/268 reads (39%) | catalogued as rs1457249627, COSV72552892; called by muse, mutect2, varscan2
- GOLGA3 | c.1551C>T p.A517= | Silent (SNP) | VAF 90/212 reads (42%) | catalogued as rs780405013, COSV99212334; called by muse, mutect2, varscan2
- HDGFL1 | c.588G>A p.P196= | Silent (SNP) | VAF 62/108 reads (57%) | catalogued as rs1460048360; called by muse, varscan2
- HEPACAM2 | c.1153C>T p.L385= (on ENST00000394468 / NM_001039372.4; = p.L373= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- JPH2 | c.306C>T p.S102= | Silent (SNP) | VAF 81/281 reads (29%) | catalogued as rs779455211, COSV100652566; called by muse, mutect2, varscan2
- LAMA1 | c.3918G>A p.T1306= | Silent (SNP) | VAF 142/346 reads (41%) | catalogued as rs754627841, COSV67539548; called by muse, mutect2, varscan2
- NKX6-3 | c.501C>T p.P167= | Silent (SNP) | VAF 98/191 reads (51%) | catalogued as rs537683470; called by muse, mutect2, varscan2
- NOS1 | c.3273G>A p.P1091= | Silent (SNP) | VAF 202/372 reads (54%) | catalogued as rs1004551488, COSV57608306; called by muse, mutect2, varscan2
- OR2T27 | c.777C>T p.Y259= | Silent (SNP) | VAF 80/171 reads (47%) | catalogued as rs370373865, COSV100788468, COSV61281098, COSV61281472; called by muse, mutect2, varscan2
- PDE1B | c.747G>A p.S249= | Silent (SNP) | VAF 93/197 reads (47%) | catalogued as rs113265707; called by muse, mutect2, varscan2
- PDE1C | c.1932C>A p.T644= | Silent (SNP) | VAF 179/563 reads (32%) | called by muse, mutect2, varscan2
- PGM5 | c.1500G>A p.S500= | Silent (SNP) | VAF 92/210 reads (44%) | catalogued as rs137918890; called by muse, mutect2, varscan2
- PTPRF | c.4005C>T p.T1335= | Silent (SNP) | VAF 126/291 reads (43%) | catalogued as rs146415017, COSV63443806; called by muse, mutect2, varscan2
- PTPRQ | c.5931A>G p.K1977= (on ENST00000616559; = p.K1935= on NM_001145026.2) | Silent (SNP) | VAF 73/146 reads (50%) | called by muse, mutect2, varscan2
- RYR2 | c.12648G>A p.A4216= | Silent (SNP) | VAF 153/326 reads (47%) | catalogued as rs781557399, COSV63659303; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- SERPINB3 | c.1032A>T p.A344= | Silent (SNP) | VAF 88/247 reads (36%) | catalogued as COSV52191414; called by muse, mutect2, varscan2
- SIPA1L2 | c.4548C>T p.D1516= | Silent (SNP) | VAF 123/264 reads (47%) | called by muse, mutect2, varscan2
- SORCS3 | c.1032G>A p.S344= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as rs201042825, COSV63826016; called by muse, mutect2
- TANGO6 | c.531C>T p.A177= | Silent (SNP) | VAF 137/295 reads (46%) | catalogued as rs151234531; called by muse, mutect2, varscan2
- TGM4 | c.1056G>A p.T352= | Silent (SNP) | VAF 170/383 reads (44%) | catalogued as rs769188894, COSV56092648; called by muse, mutect2, varscan2
- USF3 | c.5943C>T p.P1981= | Silent (SNP) | VAF 118/281 reads (42%) | called by muse, mutect2, varscan2
- VRK1 | c.1119G>T p.T373= | Silent (SNP) | VAF 150/383 reads (39%) | called by mutect2, varscan2
- ZNF865 | c.2874C>T p.R958= | Silent (SNP) | VAF 140/499 reads (28%) | catalogued as rs1165413408; called by muse, mutect2, varscan2
- ZSCAN18 | c.1023G>A p.A341= | Silent (SNP) | VAF 191/596 reads (32%) | catalogued as rs764827147, COSV53736956; called by muse, mutect2, varscan2
- AC011525.1 | n.965G>A | RNA (SNP) | VAF 40/171 reads (23%) | called by muse, mutect2, varscan2
- C16orf91 | c.32+26C>A | Intron (SNP) | VAF 106/219 reads (48%) | called by muse, mutect2, varscan2
- COL9A3 | c.79-36G>T | Intron (SNP) | VAF 71/269 reads (26%) | catalogued as rs765923984; called by muse, mutect2, varscan2
- CYP2F1 | c.964+70C>T | Intron (SNP) | VAF 82/277 reads (30%) | catalogued as rs760853657; called by muse, mutect2, varscan2
- LAMA1 | c.8207+13C>T | Intron (SNP) | VAF 153/339 reads (45%) | called by muse, mutect2, varscan2
- LINC00479 | n.359C>T | RNA (SNP) | VAF 100/245 reads (41%) | catalogued as rs887599503; called by muse, mutect2, varscan2
- LINC01559 | n.595T>C | RNA (SNP) | VAF 110/246 reads (45%) | called by muse, mutect2, varscan2
- LIPE | c.883+1896G>A | Intron (SNP) | VAF 294/957 reads (31%) | catalogued as rs1350154478; called by muse, mutect2, varscan2
- MED16 | c.2098+306G>A | Intron (SNP) | VAF 121/472 reads (26%) | catalogued as rs770551860; called by muse, mutect2, varscan2
- MIR514A3 | n.19C>A | RNA (SNP) | VAF 5/31 reads (16%) | called by mutect2, varscan2
- PRR34 | n.323C>T | RNA (SNP) | VAF 45/240 reads (19%) | called by muse, mutect2, varscan2
- SCAF4 | c.777+48T>A | Intron (SNP) | VAF 46/96 reads (48%) | called by muse, mutect2, varscan2
- SLC7A10 | c.789-29C>T | Intron (SNP) | VAF 152/555 reads (27%) | catalogued as rs370961084; called by muse, mutect2, varscan2
- TP73 | c.186+7754A>T | Intron (SNP) | VAF 211/487 reads (43%) | catalogued as rs1167660067; called by muse, mutect2, varscan2
- TUBBP5 | n.1210G>A | RNA (SNP) | VAF 287/626 reads (46%) | called by muse, varscan2
- UGT2B27P | n.1442G>A | RNA (SNP) | VAF 153/385 reads (40%) | catalogued as rs777270252; called by muse, mutect2, varscan2
- UQCRB | c.*2168_*2169del | 3'UTR (DEL) | VAF 48/136 reads (35%) | called by mutect2, pindel, varscan2
